Somatic mutation profile of tumor specimen TCGA-A6-A567-01A (aliquot TCGA-A6-A567-01A-31D-A28G-10) from TCGA case TCGA-A6-A567, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 56.1 years (20,493 days).
Specimen TCGA-A6-A567-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 328861df-5da9-4bbf-92c4-73aded9bde52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-A567-10A (Blood Derived Normal), aliquot TCGA-A6-A567-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a085d44-6e4b-4ec9-a907-c06d02861448

The open-access MAF lists 64 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 14, Nonsense Mutation 3, 3'UTR 2, Frame Shift Del 1, Splice Site 1, RNA 1, 5'Flank 1, 5'UTR 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 67/163 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 41/68 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BTBD10 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as rs536418438; called by muse, mutect2, varscan2
- CASQ2 | c.173A>T p.E58V | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as rs764732977; ClinVar: uncertain significance; called by muse, mutect2
- CPB1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs766816862, COSV51573302; called by muse, mutect2, varscan2
- DKK2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 111/191 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs539488952, COSV53393778; called by muse, mutect2, varscan2
- DOCK6 | c.2791G>A p.A931T | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs754257812; called by muse, mutect2, varscan2
- DZIP1 | c.2099C>T p.P700L (on ENST00000347108; = p.P681L on NM_014934.5) | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61267516, COSV61269591; called by muse, mutect2
- FAM27E5 | n.276C>T | Splice Region (SNP) | VAF 47/154 reads (31%) | catalogued as rs544493136; called by muse, mutect2, varscan2
- FBXL16 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100178719; called by muse, mutect2, varscan2
- FBXL7 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs767178690, COSV61654436; called by muse, mutect2, varscan2
- IL12RB1 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs201223132, COSV59095934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCA5 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771337269, COSV63971032; called by muse, mutect2
- LYVE1 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs746141063; called by muse, mutect2, varscan2
- MALRD1 | c.5413C>T p.L1805F | Missense Mutation (SNP) | VAF 213/377 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1008698227; called by muse, mutect2, varscan2
- MAP3K12 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as COSV99913691; called by muse, mutect2, varscan2
- NEB | c.9412G>A p.D3138N | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs374760449; ClinVar: uncertain significance; called by muse, mutect2
- NXF3 | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 78/117 reads (67%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as rs201112869, COSV67703668; called by muse, mutect2, varscan2
- OR52D1 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100495269, COSV59488311; called by muse, mutect2, varscan2
- PDZRN3 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs759383088; called by muse, mutect2, varscan2
- PPP2R2B | c.19A>T p.T7S (on ENST00000394409; = p.T73S on NM_181674.2) | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs531695576, COSV100353829, COSV60771109; called by muse, mutect2, varscan2
- RASGRP3 | c.1181C>T p.T394M (on ENST00000402538 / NM_001349975.2; = p.T393M on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs370150483; called by muse, mutect2, varscan2
- SARNP | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1366473143; called by muse, mutect2, varscan2
- SH2D5 | c.1222C>T p.R408W (on ENST00000444387 / NM_001103161.2; = p.R324W on NM_001103160.2) | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs751663789, COSV56115312; called by muse, mutect2, varscan2
- SNX13 | c.2154G>T p.M718I | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV68064615; called by muse, mutect2, varscan2
- TBX18 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63736487; called by muse, mutect2, varscan2
- TEKT2 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 114/321 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs761848844; called by muse, mutect2, varscan2
- TMEM161A | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs906645800; called by muse, mutect2, varscan2
- ZBTB41 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs1405118152; called by muse, mutect2, varscan2
- ZNF471 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.201); catalogued as rs749038385; called by muse, mutect2, varscan2
- ZNF835 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV73379389; called by muse, mutect2, varscan2
- GPBP1 | c.63+1G>C p.X21_splice | Splice Site (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.141C>G p.D47E | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KCNH7 | c.2970_2977del p.D991Kfs*12 | Frame Shift Del (DEL) | VAF 31/134 reads (23%) | called by mutect2, pindel, varscan2
- OR5P2 | c.184T>G p.L62V | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- PRPF40A | c.1397G>C p.S466T | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RNF112 | c.1567G>C p.A523P | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SHANK1 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 53/140 reads (38%) | called by muse, mutect2, varscan2
- TEX30 | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, varscan2
- TRAPPC8 | c.648G>T p.Q216H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- TTN | c.7175G>T p.G2392V (on ENST00000591111; = p.G2346V on NM_003319.4) | Missense Mutation (SNP) | VAF 43/127 reads (34%) | PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- VILL | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- VNN2 | c.715A>C p.M239L | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CREG2 | c.114G>A p.V38= | Silent (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.996C>G p.G332= | Silent (SNP) | VAF 6/152 reads (4%) | catalogued as COSV101337604; called by muse, mutect2
- HS3ST2 | c.462C>T p.Y154= | Silent (SNP) | VAF 24/153 reads (16%) | called by muse, mutect2, varscan2
- KCNA1 | c.741G>A p.T247= | Silent (SNP) | VAF 44/142 reads (31%) | called by mutect2, varscan2
- KIAA1191 | c.201C>T p.L67= | Silent (SNP) | VAF 13/188 reads (7%) | catalogued as rs759249446; called by muse, mutect2
- LGR6 | c.1533C>T p.P511= (on ENST00000367278 / NM_001017403.1; = p.P459= on NM_021636.3) | Silent (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1674C>T p.D558= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as rs138192949, COSV69168586, COSV69187189; called by muse, mutect2, varscan2
- PCDHAC2 | c.447G>A p.P149= | Silent (SNP) | VAF 16/292 reads (5%) | catalogued as rs139717123; called by muse, mutect2
- PRR33 | c.756C>T p.P252= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs572344484, COSV61133403; called by muse, mutect2, varscan2
- RHCE | c.1114T>C p.L372= | Silent (SNP) | VAF 250/1172 reads (21%) | catalogued as rs1415307331; called by muse, varscan2
- RPS6KB2 | c.810C>T p.T270= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs767711171; called by muse, mutect2, varscan2
- SYNE1 | c.1785G>A p.R595= (on ENST00000367255 / NM_182961.4; = p.R602= on NM_033071.3) | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV54998207; called by muse, mutect2
- THBS2 | c.1182C>T p.S394= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs200055895, COSV64678108; called by muse, mutect2, varscan2
- TMEM200C | c.504C>T p.F168= | Silent (SNP) | VAF 64/121 reads (53%) | catalogued as rs767447802, COSV67309210; called by muse, mutect2, varscan2
- AC004947.2 | chr7:26536974 T>A | 5'Flank (SNP) | VAF 79/215 reads (37%) | called by muse, mutect2, varscan2
- ATAD3B | c.*700C>T | 3'UTR (SNP) | VAF 22/84 reads (26%) | catalogued as rs752824611, COSV58023624; called by muse, mutect2, varscan2
- CDK5RAP3 | c.*3C>T | 3'UTR (SNP) | VAF 34/101 reads (34%) | catalogued as COSV100621092, COSV100621259; called by muse, mutect2, varscan2
- MROH5 | c.-11G>T | 5'UTR (SNP) | VAF 21/47 reads (45%) | catalogued as COSV101435868; called by muse, mutect2, varscan2
- PNMA3 | chrX:153060465 C>T | 3'Flank (SNP) | VAF 40/58 reads (69%) | catalogued as rs1205507322, COSV100937548; called by muse, mutect2, varscan2
- VN1R10P | n.504C>T | RNA (SNP) | VAF 22/247 reads (9%) | called by muse, mutect2
